Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6532, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6532-01A (Primary Tumor).

TCGA - D5 - 6532

Examination: Histopathological examination

Cost of diagnostic procedure

Material: 1. Multiple organ resection – sigmoid colon

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: Cancer of the sigmoid colon. Hist. Pat adenocarcinoma invasivum.

Examination performed on:

Macroscopic description:

21 cm length of the large intestine with fat tissue of 22 x 10 x 5 cm. Ulcerous tumour sized 8 x 5 x 1.5 cm in the mucosa. The lesion surrounds 55% of the intestine circumference, narrowing its lumen; is located 11 cm from one of the cut ends and 2 cm from the opposite one. The lesion macroscopically invades through the peritoneal tissue. Minimum side margin is 0.1 cm.

Microscopic description:

Adenocarcinoma tubulare (G2).

Infiltratio carcinomatosa tunicae muscularis propriae et tela adiposae pericolicae.

Incision lines free of neoplastic lesions.

Lymphonodulitis reactiva (No X).

Final diagnosis after immunohistochemical tests No. are performed.

Compliance validated by:

Examination performed on:

Histopathological diagnosis:

Adenocarcinoma tubulare coli. Tubular adenocarcinoma of the colon.

(G2, Dukes B, Astler - Coller B2, pT3, pN0).

Compliance validated by:

Source: NCI Genomic Data Commons file aebab2e3-a0b8-4482-ae06-31f8109fbfe5 (TCGA-D5-6532.F7AB0E42-7405-4F0F-9A3D-D2B0DC0D7234.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).